Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A4OY, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A4OY-01A (Primary Tumor).

Procurement Date: Laterality: Malignant melanoma, pigmented, ulcerated, formed of nevus-like and spindle-like cells. Clark level V. Breslow's depth is 1 cm, with lymphoid infiltration.

Three lymph nodes were examined, one lymph node (inguinal) demonstrated metastasis.

Path Report: SKIN TISSUE CHECKLIST

Specimen type: Excision of lesion

Tumor site: Skin, foot (NON-glabrous - pigmented)

Tumor size: 2 x 1 x 3.5 cm

Tumor features: Ulcerated, Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade:

Lymph nodes: 1/3 positive for metastasis (Inguinal lymph node 1/3)

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Clark level V. Breslow's depth is 10 mm

ICA-0-3

Melanoma NOS 8720/3

Site: Skin, foot C44.7

hw
10/10/12

hw
10/10/12

Source: NCI Genomic Data Commons file 8fef55ae-84d1-4f9a-99eb-4b6a55f5b745 (TCGA-EB-A4OY.F5BCA762-3B92-4B86-96D9-A88C7D06967A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).